Gene-level copy-number profile of tumor specimen TCGA-VB-A8QN-01A from TCGA case TCGA-VB-A8QN, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 55.5 years (20,270 days).
Specimen TCGA-VB-A8QN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.ccb9f6eb-643c-4dea-9da2-1262dd6115ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VB-A8QN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d920048f-1505-43ab-8477-33556618ee60

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 3,781; copy number 2: 52,453; copy number 3: 3,225; copy number 4: 302.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VB-A8QN-01A-11D-A381-01): tumor purity 0.53, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:130,144,315–130,837,135, 5 genes (within-gene range 0–1): SAMD3, TMEM200A, Y_RNA, AL583803.1, SMLR1.
- chr6:136,342,281–137,972,522, 33 genes (within-gene range 0–1): MAP7, AL023284.3, AL023284.2, NDUFS5P1, RN7SKP299, AL024508.1, MAP3K5, MAP3K5-AS1, RNA5SP219, AL121933.2, PEX7, AL121933.1, AL365223.1, SLC35D3, Y_RNA, RPL35AP3, NHEG1, AL135902.1, IL20RA, IL22RA2, IFNGR1, OLIG3, BTF3L4P3, AL356234.2, AL356234.3, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865.
- chr6:145,296,545–145,311,092, 1 gene: AL023283.1.
- chr6:145,463,238–145,463,399, 1 gene: RNU1-33P.
- chr16:12,366,982–12,611,044, 6 genes: AC007598.2, AC007598.1, AC007598.3, AC131391.1, AC010333.1, AC010333.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,743. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
